Surgical pathology report (de-identified scan), TCGA case TCGA-HT-8010, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-8010-01A (Primary Tumor).

Microscopic

Sections demonstrate a mildly hypercellular infiltrating glioma. The tumor consists of a proliferation of cells with round nuclei and variably prominent perinuclear halos. Where the tumor cells exhibit mild cytologic atypia an occasional neuron demonstrates perineuronal satellitosis by tumor cells. Mitotic figures are not seen. There is no intratumoral necrosis or hemorrhage.

Only very rare MIB-1 reactive cells are present. A labeling index of <0.1% is calculated.

Diagnosis

Oligodendroglioma grade II

Source: NCI Genomic Data Commons file b1edebb5-9344-423d-9783-0499c1eef3c9 (TCGA-HT-8010.EC4DAE3C-9D46-48CB-9201-A8199139986F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).